Somatic mutation profile of tumor specimen C3N-01220-01 (aliquot CPT0076320011) from CPTAC case C3N-01220, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 51.3 years (18,748 days).
Specimen C3N-01220-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d9038eb-45bf-4812-888c-bf36a389a32c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01220-71 (Blood Derived Normal), aliquot CPT0076400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b1da6ca-7439-41a4-9436-e2072c23d8ab

The open-access MAF lists 93 somatic variants for this specimen: 53 protein-altering or splice-affecting, 25 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 25, Intron 8, Splice Site 5, Nonsense Mutation 3, Frame Shift Del 2, 3'UTR 2, RNA 2, 5'UTR 1, 5'Flank 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4715+1G>T p.X1572_splice | Splice Site (SNP) | VAF 13/64 reads (20%) | hotspot (GDC flag); catalogued as COSV57431126, COSV57439397; called by muse, mutect2, varscan2
- AFF4 | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs751474496; called by muse, mutect2, varscan2
- ANK2 | c.11333G>A p.G3778E | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); catalogued as COSV52147199, COSV52178677; called by muse, mutect2, varscan2
- ANKRD34B | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 29/216 reads (13%) | catalogued as COSV58613404; called by muse, mutect2, varscan2
- ANO2 | c.2363C>T p.P788L (on ENST00000356134 / NM_001278597.3; = p.P792L on NM_001278596.3) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370114605; called by muse, mutect2, varscan2
- ARHGAP23 | c.2439C>G p.D813E | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs1049336617; called by muse, mutect2, varscan2
- CLCN1 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1473430259, COSV58368059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYM | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs553362900, COSV99561970; called by muse, mutect2
- DOCK1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV54728364; called by muse, mutect2, varscan2
- EFR3A | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 13/176 reads (7%) | catalogued as rs764347591, COSV99602292; called by muse, mutect2
- FGD5 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV53240622; called by muse, mutect2, varscan2
- FNIP1 | c.2338C>T p.H780Y | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.253); catalogued as rs756786251; called by muse, mutect2, varscan2
- HMMR | c.508T>A p.L170M | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100700997; called by muse, mutect2, varscan2
- IQGAP3 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63254652; called by muse, mutect2, varscan2
- KANSL3 | c.2210C>G p.P737R (on ENST00000666923 / NM_001349262.2; = p.P711R on NM_001115016.3) | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs954265164; called by muse, mutect2, varscan2
- KCTD15 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 16/139 reads (12%) | catalogued as rs757471584, COSV52289992; called by muse, mutect2, varscan2
- KLHL33 | c.699G>T p.W233C | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1363315688; called by muse, mutect2, varscan2
- MYH3 | c.645G>C p.G215= | Splice Region (SNP) | VAF 66/532 reads (12%) | catalogued as COSV56862257; called by muse, mutect2, varscan2
- PCBP1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 88/508 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs368303566; called by muse, mutect2, varscan2
- QARS1 | c.1825G>A p.A609T | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as rs62621222; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TJP2 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 62/420 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142684074, COSV55271491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGGT1 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as rs1181179801; called by muse, mutect2, varscan2
- UNC13D | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 152/1068 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV99256156; called by muse, mutect2, varscan2
- ZNF638 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 39/266 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV52485440; called by muse, mutect2, varscan2
- ACAD9 | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ARHGAP12 | c.2139G>T p.L713F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ARHGEF33 | c.1221+1del | Frame Shift Del (DEL) | VAF 31/169 reads (18%) | called by mutect2, pindel, varscan2
- C1QBP | c.841A>G p.S281G | Missense Mutation (SNP) | VAF 4/89 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2
- CORIN | c.1736-12_1738del p.X579_splice | Splice Site (DEL) | VAF 31/242 reads (13%) | called by mutect2, pindel
- DNHD1 | c.2520T>A p.N840K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DOC2A | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 123/811 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK1 | c.549T>A p.S183R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- ELOVL7 | c.256-1G>C p.X86_splice | Splice Site (SNP) | VAF 19/105 reads (18%) | called by muse, mutect2, varscan2
- HAS3 | c.442T>G p.F148V | Missense Mutation (SNP) | VAF 97/688 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HELQ | c.3238G>T p.V1080L | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- IRF4 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2
- KCNG1 | c.689C>A p.A230D | Missense Mutation (SNP) | VAF 61/464 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTCAP3 | c.37C>G p.R13G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LRP6 | c.3294del p.F1098Lfs*4 | Frame Shift Del (DEL) | VAF 27/243 reads (11%) | called by mutect2, pindel, varscan2
- MUC4 | c.8627G>T p.G2876V | Missense Mutation (SNP) | VAF 76/1278 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH13 | c.2283G>T p.R761S | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PIK3R4 | c.1718C>G p.A573G | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.538); called by muse, varscan2
- RECK | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RPS6KB1 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 67/484 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC44A1 | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SOBP | c.97-1G>T p.X33_splice | Splice Site (SNP) | VAF 59/348 reads (17%) | called by muse, mutect2, varscan2
- SPATA5 | c.1999T>A p.Y667N | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPIN3 | c.260A>G p.Y87C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPPL2A | c.361-1G>T p.X121_splice | Splice Site (SNP) | VAF 6/43 reads (14%) | called by mutect2, varscan2
- TAZ | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TWF1 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- VN1R1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 62/359 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- YEATS2 | c.3754G>A p.D1252N | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- AL592490.1 | c.60G>A p.A20= | Silent (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- CDC25B | c.1134C>T p.H378= (on ENST00000245960 / NM_021873.3; = p.H364= on NM_004358.4) | Silent (SNP) | VAF 47/196 reads (24%) | catalogued as rs560679507, COSV99848466; called by muse, varscan2
- COL11A1 | c.1512C>A p.S504= | Silent (SNP) | VAF 78/436 reads (18%) | called by muse, mutect2, varscan2
- DDX11 | c.1737C>T p.D579= | Silent (SNP) | VAF 90/499 reads (18%) | catalogued as rs755996490; called by muse, mutect2, varscan2
- EPYC | c.249A>G p.E83= | Silent (SNP) | VAF 32/235 reads (14%) | called by muse, mutect2, varscan2
- FAM72A | c.234G>T p.G78= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV100367265; called by muse, mutect2, varscan2
- FBXW12 | c.1392G>A p.T464= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs749755227, COSV56483295; called by muse, mutect2
- FNDC11 | c.549C>T p.H183= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as rs1352060707; called by muse, mutect2, varscan2
- KCNG1 | c.1336C>T p.L446= | Silent (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
- KIAA0930 | c.324C>G p.L108= (on ENST00000336156 / NM_001009880.2; = p.L113= on NM_015264.2) | Silent (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- KIF3C | c.1203G>T p.G401= | Silent (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- LILRB2 | c.24G>C p.L8= | Silent (SNP) | VAF 32/294 reads (11%) | called by muse, mutect2, varscan2
- LRP2 | c.9798C>T p.N3266= | Silent (SNP) | VAF 32/180 reads (18%) | catalogued as rs1481482183; called by muse, mutect2, varscan2
- MAPK8IP2 | c.711C>T p.S237= | Silent (SNP) | VAF 22/187 reads (12%) | catalogued as rs1429065925; called by muse, mutect2, varscan2
- MYOT | c.207C>T p.F69= | Silent (SNP) | VAF 49/303 reads (16%) | called by muse, mutect2, varscan2
- PAPSS2 | c.789C>T p.G263= | Silent (SNP) | VAF 125/714 reads (18%) | called by muse, mutect2, varscan2
- PCDH15 | c.5124A>G p.P1708= | Silent (SNP) | VAF 63/390 reads (16%) | called by muse, mutect2, varscan2
- PLEC | c.10155C>T p.G3385= (on ENST00000322810 / NM_201380.4; = p.G3275= on NM_000445.5) | Silent (SNP) | VAF 95/658 reads (14%) | called by muse, mutect2, varscan2
- SFTPD | c.183C>T p.G61= | Silent (SNP) | VAF 39/317 reads (12%) | catalogued as rs148973610; called by muse, mutect2, varscan2
- SLC7A3 | c.120G>T p.L40= | Silent (SNP) | VAF 64/213 reads (30%) | catalogued as COSV99979501; called by muse, mutect2, varscan2
- SMTNL2 | c.291C>T p.P97= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as rs1020958547; called by muse, mutect2, varscan2
- SYMPK | c.234C>T p.I78= | Silent (SNP) | VAF 62/387 reads (16%) | catalogued as rs188023108, COSV55615073; called by muse, mutect2, varscan2
- WDR1 | c.1377G>A p.T459= (on ENST00000382452; = p.T319= on NM_005112.5) | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as rs754699425, COSV101221170; called by muse, mutect2, varscan2
- ZNF143 | c.1641G>A p.T547= | Silent (SNP) | VAF 40/260 reads (15%) | catalogued as rs572827042, COSV55182215; called by muse, mutect2, varscan2
- ZNF627 | c.1137A>T p.R379= | Silent (SNP) | VAF 31/208 reads (15%) | called by muse, mutect2, varscan2
- ALK | c.3516-162_3516-161insAAGAT | Intron (INS) | VAF 35/142 reads (25%) | called by mutect2, varscan2*
- ARL13B | c.*786T>G | 3'UTR (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- CLDN8 | c.*16T>A | 3'UTR (SNP) | VAF 9/55 reads (16%) | catalogued as rs781440822; called by mutect2, varscan2
- CSMD3 | c.178+59896C>A | Intron (SNP) | VAF 28/856 reads (3%) | catalogued as rs941693073, COSV52103828, COSV99820987; called by muse, mutect2
- CTDSP1 | c.68-669C>A | Intron (SNP) | VAF 19/306 reads (6%) | called by muse, mutect2
- CTSA | c.195-42G>T | Intron (SNP) | VAF 71/364 reads (20%) | called by muse, mutect2, varscan2
- FAM24B | chr10:122883863 G>A | 5'Flank (SNP) | VAF 30/167 reads (18%) | called by muse, mutect2, varscan2
- MAP2K3 | c.49+3102G>A | Intron (SNP) | VAF 31/276 reads (11%) | catalogued as rs1403589133; called by muse, mutect2, varscan2
- MYH9 | c.5592+16G>T | Intron (SNP) | VAF 77/492 reads (16%) | called by muse, mutect2, varscan2
- RAB40C | chr16:630394 C>T | 3'Flank (SNP) | VAF 9/38 reads (24%) | catalogued as rs1423129951; called by muse, mutect2, varscan2
- S1PR3 | c.-148+192C>T | Intron (SNP) | VAF 165/960 reads (17%) | catalogued as rs774548704; called by muse, mutect2, varscan2
- SAYSD1 | c.208-3542T>G | Intron (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- SMIM8 | n.522G>A | RNA (SNP) | VAF 27/111 reads (24%) | catalogued as rs1206953256; called by mutect2, varscan2
- TPR | c.-103G>C | 5'UTR (SNP) | VAF 20/151 reads (13%) | called by muse, mutect2, varscan2
- ZNF658B | n.865A>T | RNA (SNP) | VAF 62/440 reads (14%) | called by muse, mutect2, varscan2
